Somatic mutation profile of tumor specimen TCGA-AB-2860-03B (aliquot TCGA-AB-2860-03B-01W-0728-08) from TCGA case TCGA-AB-2860, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute megakaryoblastic leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.3 years (22,035 days).
Specimen TCGA-AB-2860-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c345d961-7a44-4e51-b466-a46517bece5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2860-11B (Solid Tissue Normal), aliquot TCGA-AB-2860-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a36a0e12-3c16-4f51-bf68-0fa7f6f5646f

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENTPD1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 74/338 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV64602735; called by muse, varscan2
- HECTD1 | c.4108G>T p.D1370Y | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101237571; called by muse, mutect2
- MNDA | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63741284; called by muse, mutect2, varscan2
- MUC16 | c.26597C>T p.S8866L | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.96); catalogued as rs1453711124, COSV67476915; called by muse, mutect2, varscan2
- NPFFR2 | c.644T>C p.F215S | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100441452; called by muse, mutect2
- PLOD1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1260402112, COSV52142288, COSV52146884; called by muse, mutect2, varscan2
- ARSL | c.930C>T p.F310= | Silent (SNP) | VAF 22/475 reads (5%) | catalogued as COSV101140823; called by muse, mutect2
- CLIP2 | c.2247C>T p.I749= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs782307517, COSV56281450; called by muse, mutect2, varscan2
- FRAS1 | c.945C>T p.C315= | Silent (SNP) | VAF 75/324 reads (23%) | catalogued as COSV53624235; called by muse, mutect2, varscan2
- HS3ST1 | c.612G>A p.L204= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV50024231; called by muse, mutect2, varscan2
- DCHS2 | n.2022A>T | RNA (SNP) | VAF 51/255 reads (20%) | catalogued as COSV59731007; called by muse, mutect2, varscan2
- NBPF11 | c.-548-3127del | Intron (DEL) | VAF 28/172 reads (16%) | called by mutect2, pindel, varscan2
